Somatic mutation profile of tumor specimen TCGA-CV-6960-01A (aliquot TCGA-CV-6960-01A-41D-2012-08) from TCGA case TCGA-CV-6960, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 49.8 years (18,194 days).
Specimen TCGA-CV-6960-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ce81543f-c98f-4384-b9ca-ef95676b1cc5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-6960-10A (Blood Derived Normal), aliquot TCGA-CV-6960-10A-01D-2013-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1cec22f3-500e-47c1-b281-cc606ca4fb67

The open-access MAF lists 198 somatic variants for this specimen: 149 protein-altering or splice-affecting, 44 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 122, Silent 44, Frame Shift Del 11, Nonsense Mutation 8, Splice Site 4, Intron 2, In Frame Del 2, Frame Shift Ins 1, Translation Start Site 1, 5'UTR 1, RNA 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3019G>C p.G1007R | Missense Mutation (SNP) | VAF 20/64 reads (31%) | hotspot (GDC flag); SIFT tolerated (0.1); PolyPhen possibly damaging (0.797); catalogued as COSV55882140; called by muse, mutect2, varscan2
- AAR2 | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 80/166 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV100299473; called by muse, mutect2, varscan2
- ABI2 | c.557T>A p.M186K (on ENST00000295851 / NM_001375719.1; = p.M180K on NM_005759.7 and 35 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as COSV99652371; called by muse, mutect2, varscan2
- ACOX2 | c.32G>A p.G11E | Missense Mutation (SNP) | VAF 64/179 reads (36%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.276); catalogued as COSV100250337; called by muse, mutect2, varscan2
- ADAMTS12 | c.2492del p.G831Afs*8 | Frame Shift Del (DEL) | VAF 10/34 reads (29%) | catalogued as COSV61279223; called by mutect2, pindel, varscan2
- ADAMTS3 | c.2176C>T p.L726F | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.361); catalogued as COSV99712440; called by muse, mutect2, varscan2
- ADGRL3 | c.2501C>G p.T834R (on ENST00000506720 / NM_001322402.2; = p.T766R on NM_015236.6) | Missense Mutation (SNP) | VAF 67/221 reads (30%) | SIFT tolerated (0.39); PolyPhen benign (0.023); catalogued as COSV101547454, COSV99072522; called by muse, mutect2, varscan2
- AMPH | c.1448C>T p.A483V | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs1401696003, COSV100344137; called by muse, mutect2, varscan2
- ANK2 | c.11521C>G p.P3841A | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.742); catalogued as COSV100004860; called by muse, mutect2, varscan2
- APLP1 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs375567499; called by muse, mutect2, varscan2
- ARFGEF1 | c.1338-1G>T p.X446_splice | Splice Site (SNP) | VAF 12/25 reads (48%) | catalogued as COSV99145677; called by muse, mutect2, varscan2
- ARHGEF15 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs761325531, COSV62725841; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID2 | c.644G>T p.G215V | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100537168; called by muse, mutect2, varscan2
- ARMC2 | c.696G>T p.R232S | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV100933721; called by muse, mutect2, varscan2
- ASPHD2 | c.922G>C p.G308R | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313671; called by muse, mutect2, varscan2
- ATP8A1 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.844); catalogued as COSV100047595; called by muse, mutect2, varscan2
- BRWD3 | c.688G>T p.V230F | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.33); catalogued as COSV100956677; called by muse, mutect2, varscan2
- C8A | c.389G>A p.C130Y | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63483326; called by muse, mutect2, varscan2
- CABIN1 | c.4580A>G p.Y1527C | Missense Mutation (SNP) | VAF 86/244 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99574283; called by muse, mutect2, varscan2
- CADPS2 | c.3133G>A p.A1045T | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.995); catalogued as COSV100466897; called by muse, mutect2, varscan2
- CBY2 | c.1341G>T p.R447S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV100137927; called by muse, mutect2, varscan2
- CCR2 | c.692G>T p.R231L | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as rs746514238, COSV52747978, COSV99432909; called by muse, mutect2, varscan2
- CDH19 | c.2048G>C p.R683T | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100052605; called by muse, mutect2, varscan2
- CHD5 | c.4973G>T p.S1658I | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.076); catalogued as COSV99315590; called by muse, mutect2, varscan2
- CNGA3 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 98/194 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99737709; called by muse, mutect2, varscan2
- COL11A1 | c.4555-1G>T p.X1519_splice | Splice Site (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100618399, COSV62175806; called by muse, mutect2, varscan2
- COL11A1 | c.1844G>T p.R615M | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100618400, COSV62178867; called by muse, mutect2, varscan2
- COL12A1 | c.7540G>A p.D2514N | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1290017453, COSV100486859; called by mutect2, varscan2
- COL22A1 | c.316C>T p.R106W | Missense Mutation (SNP) | VAF 17/22 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs767596054, COSV100279026; called by muse, mutect2, varscan2
- COL3A1 | c.295C>A p.P99T | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100483250, COSV100483977; called by muse, mutect2, varscan2
- COL6A3 | c.3545C>A p.P1182Q | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99802536; called by muse, mutect2, varscan2
- CTNND2 | c.593C>T p.T198M | Missense Mutation (SNP) | VAF 46/153 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.127); catalogued as rs141302945; called by muse, mutect2, varscan2
- CUL3 | c.1253T>G p.L418R | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100025024; called by muse, mutect2, varscan2
- DCLK1 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as rs1340568626, COSV55173920; called by muse, mutect2, varscan2
- DCUN1D3 | c.365C>A p.P122H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100177122; called by muse, mutect2, varscan2
- DMRT3 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs773584030, COSV99506054; called by muse, mutect2, varscan2
- DOCK10 | c.1985C>A p.T662K | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.23); catalogued as COSV99292393; called by muse, mutect2, varscan2
- DPPA3 | c.70del p.R24Gfs*14 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as COSV61503067; called by mutect2, pindel, varscan2
- DPRX | c.4C>A p.P2T | Missense Mutation (SNP) | VAF 39/91 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.009); catalogued as COSV100934147; called by muse, mutect2, varscan2
- DYRK4 | c.1310C>G p.S437W | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as rs141423818, COSV99158641; called by muse, mutect2, varscan2
- ERBB4 | c.1844A>T p.H615L | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV99636433; called by muse, mutect2, varscan2
- FAM155A | c.1369G>T p.E457* | Nonsense Mutation (SNP) | VAF 34/57 reads (60%) | catalogued as COSV101030952; called by muse, mutect2, varscan2
- FAT4 | c.12828G>T p.K4276N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV58705627; called by muse, mutect2
- FCN2 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/47 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99391352, COSV99391451; called by muse, mutect2, varscan2
- FGD3 | c.1753C>A p.L585M | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV100491045, COSV61596484; called by muse, mutect2, varscan2
- FSCB | c.2056C>T p.P686S | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT tolerated (0.62); PolyPhen benign (0.188); catalogued as COSV100470048, COSV61217922; called by muse, varscan2
- G6PC2 | c.716C>A p.A239D | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99960978; called by muse, mutect2, varscan2
- GCNT2 | c.266C>T p.S89F | Missense Mutation (SNP) | VAF 32/77 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101097399, COSV101097774; called by muse, mutect2, varscan2
- GPC5 | c.765G>C p.M255I | Missense Mutation (SNP) | VAF 31/58 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs959752298, COSV100996396; called by muse, mutect2, varscan2
- GPC5 | c.1690G>C p.V564L | Missense Mutation (SNP) | VAF 58/94 reads (62%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.003); catalogued as COSV100996398; called by muse, mutect2, varscan2
- GPER1 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.73); PolyPhen benign (0.438); catalogued as rs771368557, COSV99867235, COSV99867518; called by muse, mutect2, varscan2
- GPR139 | c.731G>C p.R244P | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100430093; called by muse, mutect2, varscan2
- GRIN3A | c.568G>A p.V190M | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.922); catalogued as rs1179181875, COSV100701967; called by muse, mutect2, varscan2
- GTF2IRD1 | c.2735C>G p.S912C (on ENST00000265755 / NM_016328.3; = p.S897C on NM_005685.4) | Missense Mutation (SNP) | VAF 24/52 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.994); catalogued as COSV99735902; called by muse, mutect2, varscan2
- GTF3C3 | c.1616G>C p.R539P | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.381); catalogued as COSV55831553, COSV99827134; called by muse, mutect2, varscan2
- HCAR3 | c.530G>A p.C177Y | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100811902; called by muse, mutect2, varscan2
- HEATR5B | c.4813G>T p.E1605* | Nonsense Mutation (SNP) | VAF 16/46 reads (35%) | catalogued as COSV99250501; called by muse, mutect2, varscan2
- HSPA14 | c.733A>T p.R245* | Nonsense Mutation (SNP) | VAF 33/99 reads (33%) | catalogued as COSV101000716; called by muse, mutect2, varscan2
- IGHV1OR21-1 | c.93G>T p.K31N | Missense Mutation (SNP) | VAF 57/211 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.446); catalogued as rs1454255609; called by muse, mutect2, varscan2
- IL1A | c.584C>T p.A195V | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.568); catalogued as rs1432825571, COSV99641573; called by muse, mutect2, varscan2
- ITGA4 | c.2619G>C p.L873F | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.65); PolyPhen benign (0.012); catalogued as COSV101223850, COSV67897906; called by muse, mutect2
- KCNT2 | c.2141A>G p.Y714C | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99657677; called by muse, mutect2, varscan2
- KRTAP11-1 | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 36/97 reads (37%) | SIFT tolerated (0.59); PolyPhen benign (0.041); catalogued as COSV100190898, COSV60094376; called by muse, mutect2, varscan2
- LAMA2 | c.5596A>G p.M1866V | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.021); catalogued as rs772179469, COSV70358153; called by muse, mutect2, varscan2
- LAMB1 | c.3696C>G p.D1232E | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99741968; called by muse, mutect2, varscan2
- LARGE1 | c.1165G>T p.V389L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.14); catalogued as COSV100506658; called by muse, mutect2, varscan2
- LIPI | c.148G>T p.V50L | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.72); PolyPhen benign (0.015); catalogued as COSV100754071; called by muse, mutect2, varscan2
- LRP1 | c.1546G>A p.G516R | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs373613577, COSV99677902; called by muse, mutect2, varscan2
- LRP2 | c.2041G>T p.D681Y | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV55572408; called by muse, mutect2, varscan2
- LRRC4C | c.898C>G p.H300D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.674); catalogued as COSV99540328; called by muse, mutect2, varscan2
- MAP4K4 | c.1417G>C p.E473Q | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.954); catalogued as COSV100156213; called by muse, varscan2
- MARCHF2 | c.52G>A p.G18S | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0); catalogued as rs141281179; called by muse, varscan2
- MBD5 | c.4053C>A p.S1351R | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV101290311; called by muse, mutect2, varscan2
- MYH1 | c.4084C>A p.Q1362K | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV99877267; called by muse, mutect2, varscan2
- MYH9 | c.4051G>C p.A1351P | Missense Mutation (SNP) | VAF 31/90 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.529); catalogued as COSV99340101; called by muse, mutect2, varscan2
- MYO15A | c.9760T>A p.Y3254N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV99235015; called by muse, mutect2, varscan2
- MYO3B | c.2266G>A p.A756T | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.393); catalogued as COSV100512228; called by muse, mutect2
- NPAS3 | c.898C>A p.H300N (on ENST00000356141 / NM_001164749.2; = p.H268N on NM_022123.3) | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as rs777877727, COSV100639818; called by muse, mutect2, varscan2
- NPR3 | c.1387C>G p.R463G | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.03); catalogued as COSV54084557, COSV99424038; called by muse, mutect2
- NPVF | c.346A>G p.M116V | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99760344; called by muse, mutect2, varscan2
- NSD1 | c.5032G>T p.G1678W | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729201, COSV100729954; called by muse, mutect2, varscan2
- NTM | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as rs1329907592, COSV66180333; called by muse, mutect2, varscan2
- OPRPN | c.404T>G p.L135R | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.028); catalogued as COSV101271116; called by muse, mutect2, varscan2
- OR4A15 | c.762C>A p.F254L | Missense Mutation (SNP) | VAF 55/283 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.46); catalogued as rs749826089, COSV59033723, COSV59035423; called by muse, mutect2, varscan2
- OR56A1 | c.8C>A p.S3* | Nonsense Mutation (SNP) | VAF 42/147 reads (29%) | catalogued as COSV100360581; called by muse, mutect2, varscan2
- PCDH10 | c.2324C>A p.A775D | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.617); catalogued as rs756864647, COSV99994838; called by muse, mutect2, varscan2
- PNLIPRP1 | c.703A>G p.T235A | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as COSV100724594; called by muse, mutect2, varscan2
- POLA2 | c.886C>G p.L296V | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.079); catalogued as COSV99641535; called by muse, mutect2, varscan2
- PON1 | c.179A>C p.N60T | Missense Mutation (SNP) | VAF 51/418 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as COSV99732744; called by muse, mutect2, varscan2
- POU3F4 | c.943C>T p.L315F | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100937367; called by muse, mutect2, varscan2
- PRDM11 | c.767G>A p.R256Q (on ENST00000530656 / NM_001359633.1; = p.R222Q on NM_001256695.1) | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.873); catalogued as rs984566309, COSV99770699; called by muse, mutect2, varscan2
- PROSER2 | c.715G>T p.G239C | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99509077; called by muse, mutect2, varscan2
- PTPN1 | c.981C>G p.F327L | Missense Mutation (SNP) | VAF 35/163 reads (21%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as COSV100860630; called by muse, mutect2, varscan2
- RAI14 | c.1201C>T p.P401S | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.001); catalogued as COSV54292533, COSV99465010; called by muse, mutect2, varscan2
- RASGEF1A | c.1433T>A p.L478Q | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV100988746; called by muse, mutect2, varscan2
- RELN | c.4146-1G>T p.X1382_splice | Splice Site (SNP) | VAF 18/198 reads (9%) | catalogued as COSV100635218; called by muse, mutect2
- RFPL4B | c.385G>T p.D129Y | Missense Mutation (SNP) | VAF 23/65 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV101480744, COSV71437884; called by muse, mutect2, varscan2
- RFPL4B | c.497C>A p.P166Q | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as COSV101480745; called by muse, mutect2, varscan2
- RGL3 | c.1697C>A p.P566H | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.027); catalogued as COSV100993147; called by muse, mutect2, varscan2
- RIMS2 | c.3299G>T p.G1100V (on ENST00000666250 / NM_001348490.2; = p.G908V on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as COSV99213432; called by muse, mutect2, varscan2
- RYR2 | c.8741C>A p.T2914K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV100773420; called by muse, mutect2, varscan2
- SDR9C7 | c.598A>G p.I200V | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.096); catalogued as COSV99524732; called by muse, mutect2, varscan2
- SERPINA1 | c.931C>A p.H311N | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV100872230; called by muse, mutect2, varscan2
- SFTPA2 | c.135C>A p.D45E | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as rs370764679, COSV100958881; called by muse, mutect2, varscan2
- SI | c.871T>C p.S291P | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV52275499; called by muse, mutect2, varscan2
- SIGLEC1 | c.1737C>G p.D579E | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.657); catalogued as COSV52467456, COSV99171539; called by muse, mutect2, varscan2
- SIGLEC12 | c.1569C>A p.D523E (on ENST00000291707 / NM_053003.4; = p.D405E on NM_033329.2) | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.044); catalogued as COSV52458979, COSV99389688; called by muse, mutect2, varscan2
- SIPA1L1 | c.3880G>A p.A1294T | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.502); catalogued as COSV62171805; called by muse, mutect2, varscan2
- SLC39A12 | c.1999C>A p.L667M (on ENST00000377369 / NM_001145195.2; = p.L630M on NM_152725.3) | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV101070226; called by muse, mutect2, varscan2
- SLC4A10 | c.1322C>G p.P441R (on ENST00000446997 / NM_001354461.2; = p.P411R on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99766540; called by muse, mutect2, varscan2
- SLITRK5 | c.1351C>A p.R451S | Missense Mutation (SNP) | VAF 36/58 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0.154); catalogued as rs1414302227, COSV100281383, COSV61527288; called by muse, mutect2, varscan2
- SPAG16 | c.1352T>C p.V451A | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV59130988; called by muse, mutect2, varscan2
- SPATA31A1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 39/489 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as rs1263699676; called by muse, mutect2, varscan2
- SPPL2C | c.551A>T p.D184V | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100234226; called by muse, mutect2, varscan2
- SRARP | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.63); PolyPhen benign (0.02); catalogued as rs771269124, COSV100273085; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.145C>A p.P49T | Missense Mutation (SNP) | VAF 33/100 reads (33%) | PolyPhen benign (0.006); catalogued as COSV100085918; called by muse, mutect2, varscan2
- SVEP1 | c.8237G>T p.G2746V | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99930120; called by muse, mutect2, varscan2
- SYDE2 | c.2483G>A p.G828E | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99320741; called by muse, mutect2
- TAF4B | c.1772C>T p.S591L | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs776819395, COSV99301226; called by muse, varscan2
- TAF4B | c.1777C>T p.Q593* | Nonsense Mutation (SNP) | VAF 10/25 reads (40%) | catalogued as COSV99299421; called by muse, varscan2
- TENM1 | c.7505A>G p.N2502S | Missense Mutation (SNP) | VAF 64/99 reads (65%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100951312; called by muse, mutect2, varscan2
- TGFB2 | c.1137C>A p.C379* | Nonsense Mutation (SNP) | VAF 29/90 reads (32%) | catalogued as COSV100860546; called by muse, mutect2, varscan2
- TMEM255A | c.743A>G p.D248G | Missense Mutation (SNP) | VAF 27/38 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100550591; called by muse, mutect2, varscan2
- TPI1 | c.116C>T p.A39V (on ENST00000229270; = p.A2V on NM_000365.6) | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.078); catalogued as rs781891860, COSV99979206; called by muse, mutect2, varscan2
- TRPC3 | c.2756G>C p.R919T (on ENST00000379645 / NM_001366479.2; = p.R846T on NM_003305.2) | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.916); catalogued as COSV53382658, COSV99312391; called by muse, mutect2, varscan2
- VIT | c.1576G>C p.E526Q (on ENST00000389975 / NM_001177969.1; = p.E541Q on NM_053276.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs763622419, COSV101007824; called by muse, mutect2, varscan2
- VPS13C | c.10385G>T p.G3462V (on ENST00000644861 / NM_020821.3; = p.G3419V on NM_017684.5) | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99830741; called by muse, mutect2, varscan2
- ZNF385B | c.317C>T p.T106I | Missense Mutation (SNP) | VAF 38/131 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.667); catalogued as COSV100416573; called by muse, mutect2, varscan2
- ZRANB3 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99925198; called by muse, mutect2, varscan2
- ZW10 | c.144A>T p.E48D | Missense Mutation (SNP) | VAF 66/139 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.137); catalogued as COSV99563013; called by muse, mutect2, varscan2
- AGAP4 | c.1723G>A p.E575K | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- ARID3C | c.956del p.P319Qfs*7 | Frame Shift Del (DEL) | VAF 17/61 reads (28%) | called by mutect2, pindel, varscan2
- BMS1 | c.2371G>T p.V791L | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- CD27 | c.392_398del p.R131Lfs*4 | Frame Shift Del (DEL) | VAF 24/75 reads (32%) | called by mutect2, pindel, varscan2
- CDC45 | c.1489del p.L497* | Frame Shift Del (DEL) | VAF 23/85 reads (27%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.2865_2872del p.E956Sfs*20 (on ENST00000651564; = p.E909Sfs*20 on NM_015692.5) | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- CPNE2 | c.48del p.M17Wfs*14 | Frame Shift Del (DEL) | VAF 15/74 reads (20%) | called by mutect2, pindel, varscan2
- DOCK6 | c.5764C>T p.Q1922* | Nonsense Mutation (SNP) | VAF 21/65 reads (32%) | called by muse, mutect2
- GNAI1 | c.137_146del p.K46Mfs*2 | Frame Shift Del (DEL) | VAF 21/36 reads (58%) | called by mutect2, pindel*
- GTF2H3 | c.341del p.E114Gfs*5 | Frame Shift Del (DEL) | VAF 20/71 reads (28%) | called by mutect2, pindel, varscan2
- IGLV5-37 | c.346A>T p.M116L | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- KBTBD4 | c.581_584del p.I194Tfs*15 | Frame Shift Del (DEL) | VAF 23/93 reads (25%) | called by mutect2, pindel, varscan2
- OR13F1 | c.524dup p.N175Kfs*6 | Frame Shift Ins (INS) | VAF 26/128 reads (20%) | called by mutect2, pindel, varscan2
- PRAMEF10 | c.577T>A p.S193T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.79); called by mutect2, varscan2
- SMG1 | c.8793_8801del p.R2931_H2934delinsS | In Frame Del (DEL) | VAF 5/33 reads (15%) | called by mutect2, pindel, varscan2
- SPANXB1 | c.93G>A p.M31I | Missense Mutation (SNP) | VAF 59/467 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- TMEM79 | c.1098del p.E366Dfs*41 | Frame Shift Del (DEL) | VAF 43/191 reads (23%) | called by mutect2, pindel, varscan2
- VPS11 | c.280_282del p.K94del (on ENST00000620429; = p.K638del on NM_021729.6 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 33/228 reads (14%) | called by mutect2, pindel, varscan2
- ZNF45 | c.236-3_236-1del p.X79_splice | Splice Site (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- APBA2 | c.912C>T p.T304= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs1469538542, COSV101382628; called by muse, mutect2, varscan2
- ATP11C | c.321C>T p.I107= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as COSV100558878; called by muse, mutect2, varscan2
- ATP2C2 | c.2253C>T p.T751= | Silent (SNP) | VAF 30/110 reads (27%) | catalogued as rs371639847; called by muse, mutect2, varscan2
- BOD1L1 | c.6396C>A p.A2132= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV99240650; called by muse, mutect2, varscan2
- CCDC39 | c.1983C>A p.A661= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV99871057; called by muse, mutect2, varscan2
- CEBPD | c.744G>T p.R248= | Silent (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99856402; called by muse, mutect2, varscan2
- CNTN3 | c.1923G>T p.V641= | Silent (SNP) | VAF 25/45 reads (56%) | catalogued as COSV55166945; called by muse, mutect2, varscan2
- COL6A3 | c.8436C>T p.F2812= | Silent (SNP) | VAF 21/57 reads (37%) | catalogued as rs571287679, COSV55094833; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- CTNND2 | c.3198C>A p.P1066= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV100481747; called by muse, mutect2, varscan2
- DCUN1D3 | c.366C>A p.P122= | Silent (SNP) | VAF 30/125 reads (24%) | catalogued as COSV100177121; called by muse, mutect2, varscan2
- DCX | c.261G>C p.L87= | Silent (SNP) | VAF 54/81 reads (67%) | catalogued as COSV100576851; called by muse, mutect2, varscan2
- DNAJB14 | c.498A>G p.K166= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as COSV100508680; called by muse, mutect2, varscan2
- EIF2AK3 | c.2349C>T p.H783= | Silent (SNP) | VAF 116/331 reads (35%) | catalogued as COSV100304278; called by muse, mutect2, varscan2
- EML5 | c.4962T>C p.D1654= (on ENST00000380664; = p.D1662= on NM_183387.3) | Silent (SNP) | VAF 26/91 reads (29%) | catalogued as rs1414771629, COSV100716360; called by muse, mutect2, varscan2
- FGF5 | c.315G>T p.P105= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV100428123; called by muse, mutect2, varscan2
- FKTN | c.585T>A p.I195= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99795687; called by muse, mutect2, varscan2
- GRK2 | c.1542G>A p.S514= | Silent (SNP) | VAF 53/139 reads (38%) | catalogued as COSV57952154; called by muse, mutect2, varscan2
- HIF1A | c.1374G>A p.T458= | Silent (SNP) | VAF 49/130 reads (38%) | catalogued as rs781683603, COSV100049398, COSV60190761; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.180A>C p.P60= | Silent (SNP) | VAF 120/439 reads (27%) | called by muse, mutect2, varscan2
- IGLV3-9 | c.249C>A p.S83= | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- INTS8 | c.1596A>G p.L532= | Silent (SNP) | VAF 20/66 reads (30%) | catalogued as rs1344230603, COSV100569559; called by muse, mutect2, varscan2
- L3MBTL3 | c.693G>T p.A231= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs772725438, COSV104422342, COSV62386411; called by muse, mutect2, varscan2
- MAVS | c.1107C>T p.L369= | Silent (SNP) | VAF 28/92 reads (30%) | catalogued as COSV100816446; called by muse, mutect2, varscan2
- MUC17 | c.11136C>T p.S3712= | Silent (SNP) | VAF 455/657 reads (69%) | catalogued as COSV100075672; called by muse, mutect2, varscan2
- N4BP1 | c.870T>C p.S290= | Silent (SNP) | VAF 20/68 reads (29%) | catalogued as COSV99285733; called by muse, mutect2, varscan2
- NCAM1 | c.528C>A p.I176= | Silent (SNP) | VAF 26/184 reads (14%) | catalogued as COSV100378957, COSV57516213; called by muse, mutect2, varscan2
- NCAM2 | c.693C>T p.S231= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV53072605, COSV99526141; called by muse, mutect2, varscan2
- OR56B1 | c.930C>T p.A310= | Silent (SNP) | VAF 45/153 reads (29%) | catalogued as COSV100402760, COSV57723293; called by muse, mutect2, varscan2
- OR6V1 | c.673C>A p.R225= | Silent (SNP) | VAF 58/127 reads (46%) | catalogued as rs373251485, COSV101389627, COSV101389643; called by muse, mutect2, varscan2
- OR7G2 | c.114G>A p.L38= | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs141362700; called by muse, mutect2, varscan2
- PDE1C | c.189G>T p.G63= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV101275980, COSV68807336; called by muse, mutect2, varscan2
- PEX6 | c.1474C>T p.L492= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as COSV99770077; called by muse, mutect2, varscan2
- PNPLA7 | c.234T>G p.T78= | Silent (SNP) | VAF 23/97 reads (24%) | catalogued as COSV99481787; called by muse, mutect2, varscan2
- RARS1 | c.495C>T p.H165= | Silent (SNP) | VAF 9/41 reads (22%) | catalogued as COSV99199265; called by muse, mutect2, varscan2
- RBM19 | c.2856C>T p.D952= | Silent (SNP) | VAF 18/56 reads (32%) | catalogued as rs1194084507, COSV99927013; called by muse, mutect2, varscan2
- RHOBTB1 | c.642G>A p.L214= | Silent (SNP) | VAF 68/319 reads (21%) | catalogued as COSV100558784; called by muse, mutect2, varscan2
- RIN3 | c.2604G>A p.K868= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as COSV99380266; called by muse, mutect2
- RNF123 | c.1234C>T p.L412= | Silent (SNP) | VAF 26/68 reads (38%) | catalogued as COSV100571012; called by muse, mutect2, varscan2
- SI | c.2109T>C p.F703= | Silent (SNP) | VAF 28/110 reads (25%) | catalogued as COSV100017615; called by muse, mutect2, varscan2
- SLC5A12 | c.699C>T p.L233= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as rs1421764549, COSV99745693; called by muse, mutect2, varscan2
- SPANXN1 | c.21C>T p.S7= | Silent (SNP) | VAF 51/97 reads (53%) | catalogued as rs1556881959, COSV100979466; called by muse, mutect2, varscan2
- TECPR1 | c.627G>T p.L209= | Silent (SNP) | VAF 89/137 reads (65%) | catalogued as COSV101130834; called by muse, mutect2, varscan2
- TP53 | c.795G>T p.L265= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as COSV52661636, COSV52730242, COSV52895662, COSV99474023; called by muse, varscan2
- ZFP36L2 | c.1101G>T p.P367= | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV99144369; called by mutect2, varscan2
- ACTN1 | c.2361+502G>A | Intron (SNP) | VAF 18/46 reads (39%) | catalogued as rs371536376; called by muse, mutect2, varscan2
- AL353804.6 | chrX:73829072 T>G | 3'Flank (SNP) | VAF 30/40 reads (75%) | called by muse, mutect2, varscan2
- MACF1 | c.15832-8570C>G | Intron (SNP) | VAF 17/60 reads (28%) | catalogued as rs565712957, COSV99247699; called by muse, mutect2, varscan2
- SNORD114-27 | n.4T>A | RNA (SNP) | VAF 16/49 reads (33%) | called by muse, mutect2, varscan2
- TRIAP1 | c.-1del | 5'UTR (DEL) | VAF 31/124 reads (25%) | catalogued as rs752262697; called by mutect2, pindel, varscan2
